Gene-level copy-number profile of tumor specimen HTMCP-03-06-02411-01A from CGCI case HTMCP-03-06-02411, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glassy cell carcinoma; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: GX; Age at diagnosis: 42.2 years (15,398 days).
Specimen HTMCP-03-06-02411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7ebc8725-8116-45ca-88f2-280a97f19408.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02411-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,246 have no estimate.
https://portal.gdc.cancer.gov/files/3c0ec7d3-2b5d-4f4d-b79f-c6cecd44145a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 138; copy number 1: 14,872; copy number 2: 37,944; copy number 3: 4,964; copy number 4: 184; copy number 5: 178; copy number 6: 4; copy number 7: 6; copy number 8: 30; copy number 9: 19; copy number 11: 4; copy number 12: 1; copy number 15: 23; copy number 19: 10.

Homozygous deletions (total copy number 0; autosomes only): 138 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–141,208,376, 3 genes (within-gene range 0–1): Y_RNA, RNU6-904P, RPS16P3.
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–1): AC104164.2, MIR548BB.
- chr3:60,856,389–60,856,605, 1 gene (within-gene range 0–1): U3.
- chr4:19,455,418–20,037,972, 4 genes (within-gene range 0–2): AC024230.1, AC110767.1, AC114728.1, AC098862.1.
- chr6:75,428,407–75,500,136, 5 genes (within-gene range 0–1): MIR4463, AL445465.2, UBE2V1P15, RNU1-34P, RPL26P20.
- chr8:98,603,253–98,633,865, 2 genes (within-gene range 0–2): AP003467.1, AP003467.2.
- chr9:19,507,452–26,118,408, 93 genes (broad region; genes not listed).
- chr9:40,992,249–41,218,410, 2 genes (within-gene range 0–1): FRG1HP, PGM5P2.
- chr9:41,061,290–41,355,538, 13 genes (within-gene range 0–1): AL353763.1, BX255923.1, BX255923.2, FOXD4L6, CBWD6, MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6.
- chr9:64,810,865–65,250,826, 8 genes: BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1.
- chr11:73,951,026–73,982,843, 3 genes: DNAJB13, AP003717.1, UCP2.
- chr11:99,120,176–99,120,490, 1 gene (within-gene range 0–1): RN7SKP53.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–1): AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 271 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:173,871,653–177,618,742, 99 genes, copy number 5–19 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,256,337–38,335,514, 14 genes, copy number 5: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr8:118,189,455–118,976,619, 6 genes, copy number 7: SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P.
- chr8:126,474,189–130,017,129, 49 genes, copy number 5–8 (within-gene range 1–8): AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194.
- chr11:30,323,104–30,632,583, 5 genes, copy number 5: ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1.
- chr11:32,602,246–33,033,582, 6 genes, copy number 5 (within-gene range 4–5): CCDC73, AL049714.1, PRRG4, QSER1, Y_RNA, DEPDC7.
- chr11:34,533,014–35,020,591, 8 genes, copy number 5: AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343.
- chr13:73,054,976–73,995,056, 12 genes, copy number 5: KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1.
- chr14:22,163,238–22,501,663, 51 genes, copy number 5: TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr18:54,142,133–55,146,645, 19 genes, copy number 5: AC090666.1, MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, AC090897.1, AC091135.1, DYNAP, RAB27B, RPSAP57, AC007673.1, AC098848.1, CCDC68, MAP1LC3P, LINC01929, RNA5SP459.

Autosomal genes at a single copy (total copy number 1): 14,188. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
